Somatic mutation profile of tumor specimen C3N-03662-01 (aliquot CPT0219360006) from CPTAC case C3N-03662, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 65.0 years (23,732 days).
Specimen C3N-03662-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 318577bd-bb6a-4295-9a37-c9dbed90efce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03662-71 (Blood Derived Normal), aliquot CPT0219480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f032bd-a301-43cb-bcd6-da7b96139b9c

The open-access MAF lists 298 somatic variants for this specimen: 196 protein-altering or splice-affecting, 57 silent, 45 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 57, Intron 25, 5'UTR 10, Nonsense Mutation 9, 3'UTR 5, Splice Site 5, Splice Region 4, RNA 3, Frame Shift Del 3, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 128/340 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKRD29 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 22/385 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs750342039; called by muse, mutect2
- AP5Z1 | c.1762G>C p.D588H | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.834); catalogued as COSV62244493; called by muse, mutect2, varscan2
- ATP7B | c.3956G>A p.R1319Q | Missense Mutation (SNP) | VAF 281/853 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.086); catalogued as rs529307157, COSV54442102; called by muse, mutect2, varscan2
- BZW2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.081); catalogued as rs1271212523; called by muse, mutect2, varscan2
- CD86 | c.595G>T p.V199F (on ENST00000330540 / NM_175862.5; = p.V193F on NM_006889.4) | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52608424; called by muse, mutect2, varscan2
- CDH12 | c.520C>A p.P174T | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.913); catalogued as COSV66398206; called by muse, varscan2
- CDH9 | c.2312G>T p.G771V | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50253534, COSV99141291; called by muse, mutect2, varscan2
- CERK | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 68/330 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV53453474; called by muse, mutect2, varscan2
- CHST8 | c.1161C>G p.I387M | Missense Mutation (SNP) | VAF 167/670 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.896); catalogued as rs867158855, COSV52862517; called by muse, mutect2, varscan2
- CLVS2 | c.537G>T p.M179I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51568777; called by muse, mutect2, varscan2
- CNTNAP4 | c.2947T>C p.F983L | Missense Mutation (SNP) | VAF 106/320 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1217416420; called by muse, mutect2, varscan2
- CRYBG2 | c.4004A>G p.N1335S | Missense Mutation (SNP) | VAF 263/726 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.131); catalogued as rs554259315; called by muse, mutect2, varscan2
- CSMD3 | c.6911C>A p.P2304Q (on ENST00000297405 / NM_001363185.1; = p.P2200Q on NM_052900.3) | Missense Mutation (SNP) | VAF 48/272 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52116011; called by muse, mutect2, varscan2
- CTNNA3 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 164/524 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs769674937, COSV65597724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYTH4 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 76/284 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs201940219; called by muse, mutect2, varscan2
- DNM3 | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 138/255 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1362768272; called by muse, mutect2, varscan2
- DOP1A | c.2183A>G p.D728G | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs370284003; called by muse, mutect2, varscan2
- ELP2 | c.2077-7G>C | Splice Region (SNP) | VAF 114/669 reads (17%) | catalogued as rs1191474163; called by muse, mutect2
- FAM160A2 | c.1481C>T p.P494L (on ENST00000449352 / NM_001098794.2; = p.P508L on NM_032127.4) | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV56412305; called by muse, mutect2
- FAM205A | c.3305G>A p.S1102N | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.098); catalogued as rs1370067106; called by muse, mutect2
- FBN3 | c.4362C>G p.N1454K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.76); catalogued as COSV99561589; called by muse, mutect2, varscan2
- FMN2 | c.1224C>G p.F408L | Missense Mutation (SNP) | VAF 60/237 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV60429342; called by muse, mutect2, varscan2
- GPR148 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 49/222 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV99998458; called by muse, mutect2, varscan2
- GRM4 | c.2566C>A p.R856S | Missense Mutation (SNP) | VAF 102/473 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.253); catalogued as COSV65214075; called by muse, mutect2, varscan2
- GTF2F2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 58/188 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as rs544686461, COSV61237625; called by muse, mutect2, varscan2
- H4C5 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 77/419 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); catalogued as rs572454026, COSV100748082; called by muse, mutect2, varscan2
- KCNB2 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 67/237 reads (28%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs770363006, COSV73050496; called by muse, mutect2, varscan2
- KEAP1 | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 265/874 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV50269375, COSV50647301; called by muse, mutect2, varscan2
- KRTAP10-2 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 294/778 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs200608605; called by muse, mutect2, varscan2
- LRP1B | c.9687del p.W3229* | Frame Shift Del (DEL) | VAF 45/249 reads (18%) | catalogued as COSV67192585; called by mutect2, pindel, varscan2
- MAGEB18 | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100305687; called by muse, mutect2, varscan2
- MAGEC3 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as COSV53579858, COSV68924101; called by muse, mutect2
- MS4A3 | c.218A>G p.Q73R | Missense Mutation (SNP) | VAF 81/314 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as rs1466525192; called by muse, mutect2, varscan2
- NIPBL | c.6677C>T p.S2226L | Missense Mutation (SNP) | VAF 119/257 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as COSV99239862; called by muse, mutect2, varscan2
- OR4A5 | c.719G>C p.G240A | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100157369; called by muse, mutect2, varscan2
- OXCT1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 82/574 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs746345071, COSV99542803; called by muse, mutect2, varscan2
- PCNX2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs762362794, COSV99268842; called by muse, mutect2, varscan2
- PLD1 | c.981C>G p.I327M | Missense Mutation (SNP) | VAF 68/540 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV60574989; called by muse, mutect2, varscan2
- PRSS1 | c.404C>A p.T135N | Missense Mutation (SNP) | VAF 142/561 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs1224059005, COSV61190144; called by muse, mutect2, varscan2
- PRSS41 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 16/504 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs868758276; called by muse, mutect2
- PSG6 | c.1004G>A p.R335K | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs267605521; called by mutect2, varscan2
- PTOV1 | c.338C>G p.A113G | Missense Mutation (SNP) | VAF 151/473 reads (32%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.644); catalogued as rs1486197564; called by muse, mutect2, varscan2
- RALGAPA1 | c.5414G>A p.R1805Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368964947, COSV51896496; called by muse, mutect2, varscan2
- RANBP2 | c.4663C>T p.R1555* | Nonsense Mutation (SNP) | VAF 97/486 reads (20%) | catalogued as COSV51696089; called by muse, mutect2, varscan2
- RBM14 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as rs1340526456, COSV100036679; called by muse, mutect2
- REG1A | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs374824380; called by muse, mutect2, varscan2
- RNF40 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 132/344 reads (38%) | SIFT tolerated (0.9); PolyPhen possibly damaging (0.73); catalogued as COSV61213287; called by muse, mutect2, varscan2
- RP1L1 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 233/708 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.029); catalogued as rs377219690; called by muse, mutect2, varscan2
- RSPH4A | c.403A>G p.R135G | Missense Mutation (SNP) | VAF 120/575 reads (21%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1292455050; called by muse, mutect2, varscan2
- RUNX1T1 | c.1672C>A p.Q558K (on ENST00000265814 / NM_001198628.1; = p.Q531K on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 183/811 reads (23%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56161605; called by muse, mutect2, varscan2
- RYR2 | c.10954C>A p.P3652T | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV100773349; called by muse, mutect2, varscan2
- SCN2A | c.2155G>C p.E719Q | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99330286; called by muse, mutect2, varscan2
- SGMS2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs571313214; called by muse, mutect2, varscan2
- SNTG1 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 85/328 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99382090; called by muse, mutect2, varscan2
- SOX17 | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 61/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1400365685; called by muse, mutect2, varscan2
- SYT4 | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54900510, COSV54903502; called by muse, mutect2, varscan2
- TAF10 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs1469062169; called by muse, mutect2, varscan2
- TBCCD1 | c.1450G>T p.G484W | Missense Mutation (SNP) | VAF 215/737 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58662924; called by muse, mutect2, varscan2
- TFAP2B | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 42/227 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs934664886; called by muse, mutect2, varscan2
- TLR4 | c.250G>A p.D84N (on ENST00000355622 / NM_138554.5; = p.D44N on NM_003266.4) | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868027365; called by muse, mutect2, varscan2
- TMC2 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 60/334 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs200477138, COSV62650622; called by muse, mutect2, varscan2
- TOGARAM1 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 98/339 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs1241743737; called by muse, mutect2, varscan2
- TTLL2 | c.604C>A p.L202M | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.482); catalogued as COSV53445122; called by muse, mutect2, varscan2
- TTN | c.38646T>A p.D12882E (on ENST00000591111; = p.D5458E on NM_003319.4) | Missense Mutation (SNP) | VAF 29/114 reads (25%) | PolyPhen benign (0.011); catalogued as rs758154539; called by muse, mutect2, varscan2
- ULK1 | c.1307C>T p.T436M | Missense Mutation (SNP) | VAF 73/329 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs564209559; called by muse, mutect2, varscan2
- UQCRB | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 62/256 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs757827287; called by muse, mutect2, varscan2
- WRNIP1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 90/409 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.025); catalogued as rs1331754320; called by muse, mutect2, varscan2
- ZNF211 | c.1292G>A p.G431E (on ENST00000347302 / NM_198855.4; = p.G444E on NM_006385.5) | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as rs1424005393; called by muse, mutect2
- ZNF345 | c.452G>T p.C151F | Missense Mutation (SNP) | VAF 86/312 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756742137; called by muse, mutect2, varscan2
- ZNF578 | c.1490C>A p.S497Y | Missense Mutation (SNP) | VAF 77/243 reads (32%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.563); catalogued as COSV69736526; called by muse, mutect2, varscan2
- ZNF679 | c.39+1G>A p.X13_splice | Splice Site (SNP) | VAF 161/669 reads (24%) | catalogued as COSV55378356, COSV99739436; called by muse, mutect2, varscan2
- ZNF804A | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56445205; called by muse, mutect2, varscan2
- ZNF98 | c.117G>T p.R39S | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV63340461; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 77/440 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRA1 | c.1100T>A p.V367E | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AGTR1 | c.965C>A p.P322Q | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ALG13 | c.2948A>T p.Q983L | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ALMS1 | c.10642C>A p.L3548I | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARAP1 | c.1894A>G p.S632G (on ENST00000393609 / NM_001040118.2; = p.S387G on NM_015242.4) | Missense Mutation (SNP) | VAF 83/253 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARFGAP2 | c.481-8C>A | Splice Region (SNP) | VAF 142/533 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.1310C>A p.S437Y | Missense Mutation (SNP) | VAF 196/842 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ASB15 | c.696A>T p.K232N | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- ASCC3 | c.5155G>T p.E1719* | Nonsense Mutation (SNP) | VAF 45/183 reads (25%) | called by muse, mutect2, varscan2
- ATP10B | c.2885A>T p.Q962L | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.096); called by muse, mutect2
- ATP8B2 | c.2398G>A p.E800K (on ENST00000672630; = p.E767K on NM_001367934.1 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/236 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- C3 | c.3904A>T p.S1302C | Missense Mutation (SNP) | VAF 264/1009 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- C9orf131 | c.2606C>G p.S869C | Missense Mutation (SNP) | VAF 83/321 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CANT1 | c.937G>T p.E313* | Nonsense Mutation (SNP) | VAF 46/159 reads (29%) | called by muse, mutect2, varscan2
- CCDC166 | c.913C>A p.R305S | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC184 | c.566A>C p.E189A | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.442); called by muse, varscan2
- CCDC85A | c.1082A>G p.H361R | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- CDC42BPB | c.2887G>T p.D963Y | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CFAP54 | c.2643G>T p.R881S | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- CFAP65 | c.3206A>T p.K1069M | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CIB3 | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 98/422 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- CSMD1 | c.6613del p.D2205Tfs*75 (on ENST00000520002; = p.D2204Tfs*75 on NM_033225.6) | Frame Shift Del (DEL) | VAF 30/117 reads (26%) | called by mutect2, pindel
- DAXX | c.1936A>G p.N646D | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DENND4B | c.4228G>T p.G1410W | Missense Mutation (SNP) | VAF 84/156 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- DNMT1 | c.3445G>C p.G1149R | Missense Mutation (SNP) | VAF 329/1256 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRGX | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP15 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 68/450 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- E2F5 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 158/629 reads (25%) | called by muse, mutect2, varscan2
- ESCO1 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESPL1 | c.6343T>A p.L2115M | Missense Mutation (SNP) | VAF 116/426 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT3 | c.12647G>T p.G4216V | Missense Mutation (SNP) | VAF 112/342 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FATE1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 88/180 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FOXRED1 | c.537-1G>A p.X179_splice | Splice Site (SNP) | VAF 150/695 reads (22%) | called by muse, mutect2, varscan2
- FRY | c.5872C>A p.Q1958K | Missense Mutation (SNP) | VAF 82/218 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- GALNT1 | c.689+1G>T p.X230_splice | Splice Site (SNP) | VAF 52/174 reads (30%) | called by muse, varscan2
- GLB1L | c.452-1G>A p.X151_splice | Splice Site (SNP) | VAF 103/359 reads (29%) | called by muse, mutect2, varscan2
- GON4L | c.5440G>C p.E1814Q | Missense Mutation (SNP) | VAF 73/365 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- GRM4 | c.1417G>T p.G473W | Missense Mutation (SNP) | VAF 69/272 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HOMER1 | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- HS3ST3A1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2
- HS3ST3A1 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 265/699 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- IGHJ1 | c.37G>T p.V13F | Missense Mutation (SNP) | VAF 278/692 reads (40%) | called by muse, mutect2, varscan2
- ITGB1 | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 50/110 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITSN2 | c.2416G>T p.G806C | Missense Mutation (SNP) | VAF 59/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNA7 | c.847G>C p.V283L | Missense Mutation (SNP) | VAF 190/530 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- KCNH1 | c.927C>G p.I309M | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLHL30 | c.422T>A p.F141Y | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT17 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 305/1162 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- LCE3D | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 386/793 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- LCNL1 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LEPR | c.2725G>T p.G909C | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- LINC01148 | n.473G>C | Splice Region (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- LNX2 | c.1228A>G p.S410G | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- LPA | c.3888G>T p.Q1296H | Missense Mutation (SNP) | VAF 113/604 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPA | c.2777C>T p.S926F | Missense Mutation (SNP) | VAF 119/645 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAPK4 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 98/469 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MARCHF6 | c.335-5G>C | Splice Region (SNP) | VAF 198/369 reads (54%) | called by muse, mutect2, varscan2
- MCCC1 | c.451G>A p.G151S | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MESP2 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 166/548 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- MGAT5B | c.1287G>A p.M429I | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- MMUT | c.1915G>C p.A639P | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC16 | c.41780C>A p.T13927K | Missense Mutation (SNP) | VAF 80/245 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- MUC19 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MYH8 | c.2732T>C p.L911P | Missense Mutation (SNP) | VAF 146/464 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYH9 | c.1934C>T p.T645I | Missense Mutation (SNP) | VAF 179/978 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NBEAL1 | c.4990A>T p.N1664Y | Missense Mutation (SNP) | VAF 69/275 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- NEDD4L | c.2475C>A p.N825K (on ENST00000400345 / NM_001144967.3; = p.N805K on NM_015277.6) | Missense Mutation (SNP) | VAF 36/201 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- NIN | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 46/229 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NIPBL | c.6551C>G p.S2184* | Nonsense Mutation (SNP) | VAF 35/90 reads (39%) | called by muse, mutect2, varscan2
- NSUN7 | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 96/287 reads (33%) | called by muse, mutect2, varscan2
- OFD1 | c.2809G>T p.E937* | Nonsense Mutation (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- OR2A25 | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 102/416 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- OR51T1 | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 49/275 reads (18%) | called by muse, mutect2, varscan2
- OR6T1 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- OR8G5 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR9K2 | c.904T>C p.S302P (on ENST00000305377; = p.S280P on NM_001005243.1) | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- PABPC1 | c.1538A>G p.Y513C | Missense Mutation (SNP) | VAF 100/559 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- PABPC4L | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 78/225 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PCMT1 | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.305); called by muse, mutect2
- PCSK5 | c.1313-1G>C p.X438_splice | Splice Site (SNP) | VAF 68/241 reads (28%) | called by muse, mutect2, varscan2
- PKHD1 | c.8663T>C p.V2888A | Missense Mutation (SNP) | VAF 87/419 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- POGK | c.1546G>A p.D516N | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PPP1R3A | c.1840A>G p.T614A | Missense Mutation (SNP) | VAF 73/369 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PREPL | c.1564G>A p.D522N | Missense Mutation (SNP) | VAF 133/553 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- PROM2 | c.2414A>T p.Y805F | Missense Mutation (SNP) | VAF 53/248 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- PRRC2B | c.2512C>T p.Q838* | Nonsense Mutation (SNP) | VAF 49/260 reads (19%) | called by muse, mutect2, varscan2
- RAG1 | c.1249C>A p.Q417K | Missense Mutation (SNP) | VAF 248/984 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- REG1A | c.91C>A p.Q31K | Missense Mutation (SNP) | VAF 141/571 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, varscan2
- RFX4 | c.559C>A p.L187I (on ENST00000392842 / NM_213594.3; = p.L93I on NM_032491.6) | Missense Mutation (SNP) | VAF 117/421 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- RIMS2 | c.2278G>A p.G760R (on ENST00000666250 / NM_001348490.2; = p.G568R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.10650A>T p.R3550S | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- RYR3 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SHB | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 78/330 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIM1 | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- SLC4A4 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLIT1 | c.1361T>G p.L454R | Missense Mutation (SNP) | VAF 154/440 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ST14 | c.1610G>A p.C537Y | Missense Mutation (SNP) | VAF 82/1008 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SUGP2 | c.827dup p.S277Kfs*3 | Frame Shift Ins (INS) | VAF 89/367 reads (24%) | called by mutect2, pindel, varscan2
- SUSD1 | c.684G>T p.E228D | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- SVIL | c.1496C>A p.P499H | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TACC1 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 156/585 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TBC1D4 | c.3487G>T p.V1163F | Missense Mutation (SNP) | VAF 110/364 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- TDRD10 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 176/312 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM68 | c.218T>G p.I73S | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- TMPRSS11B | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TMPRSS7 | c.354C>A p.N118K (on ENST00000452346; = p.N6K on NM_001042575.2) | Missense Mutation (SNP) | VAF 65/364 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TNFSF10 | c.67A>G p.T23A | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49B | c.140C>G p.P47R | Missense Mutation (SNP) | VAF 155/654 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TRIML1 | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, varscan2
- UBAC1 | c.195C>G p.H65Q | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ULBP3 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USF3 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 83/413 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- USH2A | c.4055G>T p.W1352L | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- USP33 | c.2558A>T p.Q853L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- WWC2 | c.2672del p.P891Qfs*6 | Frame Shift Del (DEL) | VAF 34/128 reads (27%) | called by mutect2, pindel, varscan2
- ZBTB47 | c.737A>G p.H246R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZEB1 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF318 | c.3859A>C p.K1287Q | Missense Mutation (SNP) | VAF 48/252 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF470 | c.1414C>G p.Q472E | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF676 | c.753T>A p.H251Q (on ENST00000650058; = p.H219Q on NM_001001411.3) | Missense Mutation (SNP) | VAF 88/398 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZSCAN5C | c.1030C>A p.H344N | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- AGBL1 | c.2682C>A p.P894= | Silent (SNP) | VAF 30/206 reads (15%) | called by muse, mutect2, varscan2
- AKAP8 | c.627C>T p.P209= | Silent (SNP) | VAF 99/334 reads (30%) | catalogued as rs1463186776; called by muse, mutect2, varscan2
- ARFGEF3 | c.5007T>C p.F1669= | Silent (SNP) | VAF 29/146 reads (20%) | called by muse, mutect2, varscan2
- ASPM | c.3135C>G p.L1045= | Silent (SNP) | VAF 52/260 reads (20%) | called by muse, mutect2, varscan2
- BARD1 | c.1182A>T p.T394= | Silent (SNP) | VAF 65/287 reads (23%) | called by muse, mutect2, varscan2
- CELSR1 | c.5014C>T p.L1672= | Silent (SNP) | VAF 177/528 reads (34%) | catalogued as COSV99417531; called by muse, mutect2, varscan2
- COX4I2 | c.267T>C p.N89= | Silent (SNP) | VAF 1060/1837 reads (58%) | catalogued as rs148439135; called by muse, mutect2, varscan2
- CSMD3 | c.5217C>T p.L1739= (on ENST00000297405 / NM_001363185.1; = p.L1635= on NM_052900.3) | Silent (SNP) | VAF 57/267 reads (21%) | called by muse, mutect2, varscan2
- CUX1 | c.1254C>A p.R418= (on ENST00000437600 / NM_181500.4; = p.R420= on NM_001913.5) | Silent (SNP) | VAF 116/476 reads (24%) | called by muse, mutect2
- CYP2A7 | c.1185G>A p.L395= | Silent (SNP) | VAF 79/290 reads (27%) | catalogued as rs762451153; called by muse, mutect2, varscan2
- DDR2 | c.1038C>T p.I346= | Silent (SNP) | VAF 283/509 reads (56%) | called by muse, mutect2, varscan2
- DNAH9 | c.8595C>A p.A2865= | Silent (SNP) | VAF 36/97 reads (37%) | called by muse, mutect2, varscan2
- DSEL | c.3066G>A p.K1022= | Silent (SNP) | VAF 46/184 reads (25%) | catalogued as rs769985638; called by muse, mutect2, varscan2
- DYNAP | c.219T>C p.S73= (on ENST00000321600; = p.S47= on NM_173629.3) | Silent (SNP) | VAF 17/285 reads (6%) | called by muse, mutect2
- EPHA7 | c.1755T>C p.Y585= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs752575717; called by muse, mutect2, varscan2
- EWSR1 | c.450A>G p.Q150= | Silent (SNP) | VAF 68/415 reads (16%) | catalogued as rs756866342; called by muse, mutect2, varscan2
- FHOD3 | c.865C>T p.L289= | Silent (SNP) | VAF 11/326 reads (3%) | called by muse, mutect2
- FRAS1 | c.6531T>C p.V2177= | Silent (SNP) | VAF 34/96 reads (35%) | called by muse, mutect2, varscan2
- GLI3 | c.3321G>A p.G1107= | Silent (SNP) | VAF 116/456 reads (25%) | called by muse, mutect2, varscan2
- GSTM4 | c.102G>A p.T34= | Silent (SNP) | VAF 250/684 reads (37%) | called by muse, mutect2, varscan2
- HORMAD1 | c.228A>G p.T76= | Silent (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- HTR1E | c.117G>T p.L39= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV59507790; called by muse, mutect2, varscan2
- HYOU1 | c.528G>A p.V176= | Silent (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- INTS2 | c.939C>T p.V313= | Silent (SNP) | VAF 48/158 reads (30%) | called by muse, mutect2, varscan2
- IRF9 | c.852C>T p.N284= | Silent (SNP) | VAF 69/336 reads (21%) | called by muse, mutect2, varscan2
- ITGB8 | c.903G>C p.V301= | Silent (SNP) | VAF 48/243 reads (20%) | catalogued as COSV56012231; called by muse, mutect2, varscan2
- KLHL4 | c.1443G>T p.V481= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- KRT71 | c.411G>A p.L137= | Silent (SNP) | VAF 60/196 reads (31%) | called by muse, mutect2, varscan2
- L1CAM | c.2622C>T p.P874= | Silent (SNP) | VAF 189/353 reads (54%) | catalogued as rs782519494; called by muse, mutect2, varscan2
- LRRIQ1 | c.3690C>A p.A1230= | Silent (SNP) | VAF 132/579 reads (23%) | called by muse, mutect2, varscan2
- LRRK2 | c.6096A>G p.S2032= | Silent (SNP) | VAF 110/425 reads (26%) | called by muse, mutect2, varscan2
- MAPKBP1 | c.1173C>T p.C391= (on ENST00000456763 / NM_001128608.2; = p.C385= on NM_014994.3) | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as COSV52968149; called by muse, mutect2, varscan2
- MBOAT1 | c.948A>G p.G316= | Silent (SNP) | VAF 68/347 reads (20%) | called by muse, mutect2, varscan2
- MRPS28 | c.166T>C p.L56= | Silent (SNP) | VAF 89/394 reads (23%) | catalogued as rs1437377839; called by muse, mutect2, varscan2
- MYH4 | c.522A>T p.S174= | Silent (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2, varscan2
- NCAM2 | c.1203C>A p.P401= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs773904536, COSV53104410; called by muse, mutect2, varscan2
- NOL11 | c.840A>G p.L280= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV53522888; called by muse, mutect2
- NUP210L | c.3711C>A p.L1237= | Silent (SNP) | VAF 119/226 reads (53%) | called by muse, mutect2, varscan2
- OR4D5 | c.348T>A p.T116= | Silent (SNP) | VAF 35/128 reads (27%) | called by muse, mutect2, varscan2
- OR51T1 | c.336G>T p.L112= | Silent (SNP) | VAF 50/277 reads (18%) | called by muse, mutect2, varscan2
- OR9G4 | c.147C>A p.I49= | Silent (SNP) | VAF 11/208 reads (5%) | called by muse, mutect2
- PID1 | c.105C>T p.I35= | Silent (SNP) | VAF 20/350 reads (6%) | called by muse, mutect2
- POU3F3 | c.426A>G p.P142= | Silent (SNP) | VAF 18/151 reads (12%) | catalogued as rs1416842888; called by muse, varscan2
- PRDM14 | c.456G>A p.P152= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs562813892; called by muse, mutect2, varscan2
- REG1A | c.90C>A p.P30= | Silent (SNP) | VAF 136/562 reads (24%) | catalogued as COSV99286730; called by muse, varscan2
- SKIL | c.87G>T p.A29= | Silent (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- SPHKAP | c.312G>T p.L104= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs764292492; called by muse, mutect2, varscan2
- STARD6 | c.423A>C p.S141= | Silent (SNP) | VAF 32/167 reads (19%) | called by muse, mutect2, varscan2
- TMEM151A | c.1176C>A p.A392= | Silent (SNP) | VAF 29/310 reads (9%) | called by muse, mutect2
- TPH1 | c.72A>G p.L24= | Silent (SNP) | VAF 51/184 reads (28%) | catalogued as rs1308360093; called by muse, mutect2, varscan2
- TSPAN13 | c.345G>T p.T115= | Silent (SNP) | VAF 44/180 reads (24%) | called by muse, mutect2, varscan2
- UNC80 | c.951G>A p.V317= | Silent (SNP) | VAF 56/212 reads (26%) | catalogued as COSV55887081; called by muse, mutect2
- USP22 | c.459G>A p.R153= | Silent (SNP) | VAF 49/685 reads (7%) | called by muse, mutect2
- WDR97 | c.1116G>T p.A372= | Silent (SNP) | VAF 167/613 reads (27%) | catalogued as rs749761623, COSV59363624; called by muse, mutect2, varscan2
- ZAN | c.4281G>A p.P1427= | Silent (SNP) | VAF 26/426 reads (6%) | catalogued as rs749780554, COSV61804485; called by muse, mutect2
- ZIC4 | c.369C>A p.P123= | Silent (SNP) | VAF 104/689 reads (15%) | called by muse, mutect2, varscan2
- ZNF516 | c.2802C>G p.T934= | Silent (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- AC073310.1 | n.374T>A | RNA (SNP) | VAF 35/183 reads (19%) | called by muse, mutect2, varscan2
- AC099782.1 | n.74+1937G>A | Intron (SNP) | VAF 57/161 reads (35%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39501A>G | Intron (SNP) | VAF 84/428 reads (20%) | called by muse, mutect2, varscan2
- C4orf50 | c.-58G>C | 5'UTR (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- CADM1 | c.994+50T>A | Intron (SNP) | VAF 59/198 reads (30%) | called by muse, mutect2, varscan2
- CETP | c.118+34_118+46del | Intron (DEL) | VAF 131/498 reads (26%) | called by mutect2, pindel, varscan2
- CNTN6 | c.-398A>T | 5'UTR (SNP) | VAF 35/116 reads (30%) | called by muse, mutect2, varscan2
- COL9A1 | c.1666-36A>G | Intron (SNP) | VAF 47/265 reads (18%) | called by muse, mutect2, varscan2
- DNAH6 | c.7677+21T>C | Intron (SNP) | VAF 99/390 reads (25%) | catalogued as COSV99405933; called by muse, mutect2, varscan2
- FAM71F1 | chr7:128714123 G>A | 5'Flank (SNP) | VAF 38/604 reads (6%) | catalogued as rs1282294607; called by muse, mutect2
- FGA | c.-29C>A | 5'UTR (SNP) | VAF 92/290 reads (32%) | called by muse, mutect2, varscan2
- FGA | c.-30C>T | 5'UTR (SNP) | VAF 92/286 reads (32%) | called by muse, mutect2, varscan2
- FSHB | c.*38G>A | 3'UTR (SNP) | VAF 88/319 reads (28%) | called by muse, mutect2, varscan2
- GORASP2 | c.63+430C>T | Intron (SNP) | VAF 72/222 reads (32%) | called by muse, mutect2, varscan2
- GPR162 | c.-136G>A | 5'UTR (SNP) | VAF 22/157 reads (14%) | catalogued as rs1384539154; called by muse, mutect2, varscan2
- IFT74 | c.305+1716G>A | Intron (SNP) | VAF 92/454 reads (20%) | catalogued as rs1001728512; called by muse, mutect2, varscan2
- IGKV1D-27 | n.227G>T | RNA (SNP) | VAF 195/779 reads (25%) | catalogued as rs1259374617; called by muse, mutect2, varscan2
- KHK | c.210-215T>C | Intron (SNP) | VAF 203/773 reads (26%) | catalogued as rs1157336426; called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27220G>T | Intron (SNP) | VAF 41/227 reads (18%) | called by muse, mutect2, varscan2
- LINC02877 | n.393C>T | RNA (SNP) | VAF 20/148 reads (14%) | called by muse, mutect2, varscan2
- MINDY4 | c.*16_*35del | 3'UTR (DEL) | VAF 88/349 reads (25%) | called by mutect2, pindel
- MTCL1 | c.2967+85C>T | Intron (SNP) | VAF 68/860 reads (8%) | catalogued as rs1046020017, COSV60403578; called by muse, mutect2
- MYO9A | c.5142+611A>G | Intron (SNP) | VAF 47/315 reads (15%) | called by muse, mutect2, varscan2
- NACA | c.*35G>T | 3'UTR (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2
- NDUFA3 | c.-23C>T | 5'UTR (SNP) | VAF 14/437 reads (3%) | catalogued as rs1221529143; called by muse, mutect2
- NRK | c.-78C>G | 5'UTR (SNP) | VAF 107/184 reads (58%) | called by muse, mutect2, varscan2
- NRXN2 | c.3403+5556G>T | Intron (SNP) | VAF 103/288 reads (36%) | called by muse, mutect2, varscan2
- PARP14 | c.4941+455C>T | Intron (SNP) | VAF 70/580 reads (12%) | catalogued as rs1401405345; called by muse, mutect2, varscan2
- PCYT1A | chr3:196230069 T>C | 3'Flank (SNP) | VAF 76/152 reads (50%) | catalogued as rs371389331; called by muse, mutect2, varscan2
- PILRB | c.-217-144C>T | Intron (SNP) | VAF 22/182 reads (12%) | catalogued as rs1270430339; called by muse, varscan2
- POTEM | c.811-1177_811-1176insC | Intron (INS) | VAF 91/792 reads (11%) | called by mutect2, varscan2
- PRMT9 | c.743+1053G>A | Intron (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
- RALGPS2 | c.1326-49G>A | Intron (SNP) | VAF 35/70 reads (50%) | catalogued as COSV62679456; called by muse, mutect2, varscan2
- RBM39 | c.102-2946A>T | Intron (SNP) | VAF 26/79 reads (33%) | called by muse, varscan2
- REG1A | c.183+34C>T | Intron (SNP) | VAF 106/404 reads (26%) | called by muse, varscan2
- ROBO2 | c.3761-47G>C | Intron (SNP) | VAF 65/151 reads (43%) | called by muse, mutect2, varscan2
- RPS28 | c.-17G>T | 5'UTR (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- SGIP1 | c.1571-983A>T | Intron (SNP) | VAF 31/94 reads (33%) | called by muse, mutect2, varscan2
- SLC16A7 | c.218-3056A>T | Intron (SNP) | VAF 26/82 reads (32%) | called by mutect2, varscan2
- TFAP2A | c.890-166A>C | Intron (SNP) | VAF 26/234 reads (11%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1751C>A | 3'UTR (SNP) | VAF 21/294 reads (7%) | called by muse, mutect2
- TMPO | c.-27G>C | 5'UTR (SNP) | VAF 158/642 reads (25%) | catalogued as rs1378011572; called by muse, mutect2, varscan2
- TOLLIP | c.-91A>G | 5'UTR (SNP) | VAF 26/90 reads (29%) | called by muse, mutect2
- UMODL1 | c.603+1169C>T | Intron (SNP) | VAF 125/392 reads (32%) | catalogued as rs1330400296; called by muse, mutect2, varscan2
- XIRP2 | c.*1413A>G | 3'UTR (SNP) | VAF 48/236 reads (20%) | called by muse, mutect2, varscan2
